TCGA case TCGA-04-1349 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Gynecologic Oncology Group. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4b930a10-4b12-4428-84f9-3255b4a3bc4f

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 69 years; Vital status: Dead; Days to death: 656 days (1.8 years).

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 69.0 years (25,213 days); Year of diagnosis: 2004; Method of diagnosis: Surgical Resection; FIGO stage: Stage IV; Tumor grade: G3; Prior treatment: No.
   Pathology details: Lymphatic invasion present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Treatment intent type: Adjuvant; Days to treatment start: 1 day; Days to treatment end: 373 days (1.0 years); Number of cycles: 12; Treatment dose: 75 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 1 day; Days to treatment end: 373 days (1.0 years); Number of cycles: 12; Treatment dose: 135 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 1 day; Days to treatment end: 373 days (1.0 years); Number of cycles: 12; Treatment dose: 175 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Initial disease status: Progressive Disease; Days to treatment start: 436 days (1.2 years); Days to treatment end: 653 days (1.8 years); Number of cycles: 8; Treatment dose: 75 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Initial disease status: Progressive Disease; Days to treatment start: 436 days (1.2 years); Days to treatment end: 653 days (1.8 years); Number of cycles: 8; Treatment dose: 60 mg/m2; Route of administration: Intraperitoneal.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide; Initial disease status: Progressive Disease; Days to treatment start: 436 days (1.2 years); Days to treatment end: 653 days (1.8 years); Number of cycles: 8; Treatment dose: 750 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Initial disease status: Progressive Disease; Days to treatment start: 436 days (1.2 years); Days to treatment end: 653 days (1.8 years); Number of cycles: 8; Treatment dose: 60 mg/m2; Route of administration: Intraperitoneal.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pegylated Liposomal Doxorubicin Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 436 days (1.2 years); Days to treatment end: 653 days (1.8 years); Number of cycles: 8; Treatment dose: 30 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Initial disease status: Progressive Disease; Treatment dose: 5 mg/kg.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 70.2 years (25,641 days); Days to diagnosis: 428 days (1.2 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.

Follow-up (2 entries)
- Day 428 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 428 days (1.2 years); Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 656 days (1.8 years); Disease response: With Tumor.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-04-1349-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.1; Intermediate dimension: 0.8; Shortest dimension: 0.2.
  Slide TCGA-04-1349-01A-01-BS1: Section location: Bottom; Percent tumor cells: 79; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 20.
  Slide TCGA-04-1349-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10.
- Sample TCGA-04-1349-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 0.8; Intermediate dimension: 0.8; Shortest dimension: 0.5.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Lymphovascular invasion indicator: Yes.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Pharmaceutical therapy drug name: Avastin; Therapy regimen: Progression.
- Drug treatment 5, Route of administrations: Route of administration: IP.
- Drug treatment 8: Pharmaceutical therapy drug name: Cytoxan; Therapy regimen: Progression.
- Drug treatment 9: Pharmaceutical therapy drug name: Doxil; Therapy regimen: Progression.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 656 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 656 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 428 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-04-1349-01A-01D-0452-01): tumor purity 0.76, ploidy 3.39, whole-genome doublings 1.
